Gene-level copy-number profile of tumor specimen TCGA-XK-AAJT-01A from TCGA case TCGA-XK-AAJT, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 75.1 years (27,428 days).
Specimen TCGA-XK-AAJT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.286df95d-9c43-4702-a809-2a9dabc7e420.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XK-AAJT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5df3dce4-65a3-4bb6-8449-d4e59031fa98

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 132; copy number 1: 8,579; copy number 2: 47,029; copy number 3: 3,528; copy number 4: 541.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XK-AAJT-01A-11D-A41J-01): tumor purity 0.66, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 129 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:79,967,733–83,480,024, 30 genes: AC099671.1, AC098657.1, AC098657.2, AC098657.3, HMGB1P18, AL606519.1, HNRNPA1P64, AL596276.1, AL596276.2, AL136234.1, LINC01781, MTND2P30, RPL7P10, AL357632.1, AC093154.1, RN7SKP247, ADGRL2, HNRNPA3P14, ARID3BP1, AL138799.1, AL138799.3, MED28P8, AC117944.1, AL138799.2, ST13P20, AL157944.1, LINC01362, LINC01361, AC116099.1, LINC01712.
- chr1:192,158,462–192,185,815, 1 gene: RGS18.
- chr1:192,246,708–192,367,285, 3 genes: AL513175.1, AL513175.2, RGS21.
- chr4:30,776,257–30,793,970, 1 gene: AC097716.1.
- chr4:31,171,013–33,400,679, 11 genes: LINC02497, AC104071.1, LINC02501, LINC02506, AC097654.1, LINC02353, AC116611.1, MAPRE1P2, AC093606.1, AC093878.1, AC097535.2.
- chr4:34,657,606–35,496,003, 5 genes: AC093689.1, AC093913.1, AC020589.1, SEC63P2, RNU6-573P.
- chr4:135,045,464–135,097,658, 2 genes (within-gene range 0–1): AC104619.3, AC107463.1.
- chr4:135,792,384–136,395,471, 8 genes: AC105362.1, LINC00613, RNU1-89P, AC104136.1, AC073429.2, AC018680.1, AC073429.1, TERF1P3.
- chr4:169,612,633–170,743,718, 19 genes (within-gene range 0–2): CLCN3, HPF1, PTGES3P3, AC079768.1, AC079768.3, AC079768.4, LINC02275, AC079768.2, AC084866.2, AC084866.1, MFAP3L, AADAT, APOBEC3AP1, AC069306.1, LINC01612, LINC02512, AC074255.1, HSP90AA6P, LINC02382.
- chr8:131,129,761–131,144,948, 1 gene: AC087341.1.
- chr8:132,120,859–132,848,807, 8 genes (within-gene range 0–2): KCNQ3, HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1.
- chr13:57,991,350–62,406,916, 40 genes: RNA5SP30, LINC02338, LINC00374, AL161423.1, RNY4P29, CTAGE16P, DNAJA1P1, HMGN2P39, POLR3KP1, AL159156.1, RPP40P2, RNU7-88P, DIAPH3, DIAPH3-AS1, RN7SL375P, DIAPH3-AS2, RNY4P28, LINC00434, TARDBPP2, AL359920.1, TDRD3, RNA5SP31, LINC00378, EIF4A1P6, AL161901.1, RNY3P5, LINC01442, MIR3169, PCDH20, AL592490.1, LINC02339, RAC1P8, AL353765.1, LINC00358, LINC01075, LINC01074, LINC00459, RPL32P28, AL356102.1, SQSTM1P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 6,201. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
